Somatic mutation profile of tumor specimen HCM-BROD-0594-C43-06A (aliquot HCM-BROD-0594-C43-06A-11D-A85K-36) from HCMI case HCM-BROD-0594-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 75.4 years (27,524 days).
Specimen HCM-BROD-0594-C43-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1765624c-78a1-4b40-aa7e-d0b238422588.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0594-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0594-C43-10A-01D-A85K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e19981c7-a4d4-46f6-95b5-519260fbdfd5

The open-access MAF lists 3,529 somatic variants for this specimen: 2,221 protein-altering or splice-affecting, 1,184 silent, 124 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,028, Silent 1,184, Nonsense Mutation 118, Intron 83, Splice Region 35, Frame Shift Del 19, RNA 13, 3'UTR 12, Splice Site 12, 5'UTR 6, 3'Flank 6, 5'Flank 4.

Variants (750 of 3,529; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP1A3 | c.2491G>A p.E831K (on ENST00000545399 / NM_001256214.2; = p.E818K on NM_152296.5) | Missense Mutation (SNP) | VAF 352/850 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs587777771, CM140738, COSV57489768; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.1060C>T p.L354F | Missense Mutation (SNP) | VAF 233/575 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1555767914, COSV100802407; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.871C>T p.R291* (on ENST00000377211 / NM_001201397.1; = p.R201* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 427/615 reads (69%) | catalogued as rs104894391, CM020406; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.1657C>T p.R553* | Nonsense Mutation (SNP) | VAF 152/402 reads (38%) | catalogued as rs1303773212, COSV70342690; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- NPHP1 | c.1036C>T p.R346* (on ENST00000393272 / NM_207181.4; = p.R347* on NM_000272.5) | Nonsense Mutation (SNP) | VAF 199/427 reads (47%) | catalogued as rs765263671, CM080456, COSV57206565; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTPRT | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 318/574 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV61964623; called by muse, mutect2, varscan2
- AADACL3 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 234/591 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV100206811; called by muse, mutect2, varscan2
- AASDH | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 199/284 reads (70%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs772133272; called by muse, mutect2, varscan2
- ABCA7 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 560/1279 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54025463, COSV54032840; called by muse, mutect2, varscan2
- ABCA8 | c.1568C>A p.S523* | Nonsense Mutation (SNP) | VAF 238/577 reads (41%) | catalogued as rs866764495; called by muse, mutect2, varscan2
- ABCB11 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 187/459 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55594493, COSV55595120; called by muse, mutect2, varscan2
- ABCB5 | c.2335C>T p.Q779* (on ENST00000404938 / NM_001163941.2; = p.Q334* on NM_178559.6) | Nonsense Mutation (SNP) | VAF 181/488 reads (37%) | catalogued as COSV51718861; called by muse, mutect2, varscan2
- ABCB8 | c.857C>T p.S286F (on ENST00000297504 / NM_001282291.2; = p.S269F on NM_007188.5) | Missense Mutation (SNP) | VAF 364/904 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52505217; called by muse, mutect2, varscan2
- ABCC11 | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 463/619 reads (75%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs377008966, COSV62322643; called by muse, mutect2, varscan2
- ABCC3 | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 372/831 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53324526; called by muse, mutect2, varscan2
- ABCG1 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 129/356 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV59204181; called by muse, mutect2, varscan2
- ABCG8 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 277/673 reads (41%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs769649113, COSV55392165; called by muse, mutect2, varscan2
- AC126283.2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 228/313 reads (73%) | catalogued as COSV67097984, COSV67099039; called by muse, mutect2, varscan2
- AC131160.1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 336/826 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.287); catalogued as rs756273693, COSV100226128; called by muse, varscan2
- ACAD10 | c.1529C>T p.P510L | Missense Mutation (SNP) | VAF 151/558 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.293); catalogued as rs766574091; called by muse, mutect2, varscan2
- ACAN | c.2935G>A p.G979R | Missense Mutation (SNP) | VAF 547/1462 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779442875; called by muse, varscan2
- ACE | c.3886C>T p.Q1296* | Nonsense Mutation (SNP) | VAF 416/1030 reads (40%) | catalogued as rs1162756119; called by muse, mutect2, varscan2
- ACMSD | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 254/612 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV51609694; called by muse, mutect2, varscan2
- ACOT11 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 373/888 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs750295708, COSV100989447; called by muse, mutect2, varscan2
- ACSM5 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 264/355 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866780401; called by muse, mutect2, varscan2
- ADAM11 | c.2111G>T p.W704L | Missense Mutation (SNP) | VAF 286/749 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99567883; called by muse, mutect2, varscan2
- ADAM2 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 353/822 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55870177, COSV99697341; called by muse, mutect2, varscan2
- ADAM21 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT tolerated (0.93); PolyPhen benign (0.01); catalogued as rs866624996; called by muse, mutect2, varscan2
- ADAM22 | c.2627C>T p.S876F (on ENST00000265727 / NM_001324420.2; = p.S840F on NM_016351.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 233/625 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs201785658; called by muse, mutect2, varscan2
- ADAM7 | c.1408C>T p.P470S | Missense Mutation (SNP) | VAF 351/896 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV51536126; called by muse, mutect2, varscan2
- ADAMTS20 | c.3643G>A p.D1215N | Missense Mutation (SNP) | VAF 226/572 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV67126412; called by muse, mutect2, varscan2
- ADAMTS20 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 234/549 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.373); catalogued as COSV67130927, COSV67131880; called by muse, mutect2, varscan2
- ADAMTS20 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 151/363 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV67125970; called by muse, mutect2, varscan2
- ADAMTS4 | c.2044G>A p.G682S | Missense Mutation (SNP) | VAF 286/752 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs3134667, COSV63489947; called by muse, mutect2, varscan2
- ADAMTS9 | c.2933G>A p.G978D | Missense Mutation (SNP) | VAF 187/679 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs868693196; called by muse, mutect2, varscan2
- ADGRB3 | c.1223C>T p.S408L | Missense Mutation (SNP) | VAF 121/338 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs766735540, COSV65381042; called by muse, mutect2, varscan2
- ADGRB3 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 135/397 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1363049892, COSV65419101; called by muse, mutect2, varscan2
- ADGRB3 | c.3653G>A p.R1218K | Missense Mutation (SNP) | VAF 96/292 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53247337, COSV99485893; called by muse, mutect2, varscan2
- ADGRE1 | c.2256G>A p.W752* | Nonsense Mutation (SNP) | VAF 237/661 reads (36%) | catalogued as rs759823059; called by muse, mutect2, varscan2
- ADGRF4 | c.1281G>A p.W427* | Nonsense Mutation (SNP) | VAF 306/876 reads (35%) | catalogued as COSV51957562; called by muse, mutect2, varscan2
- ADGRG4 | c.8002G>A p.V2668I | Missense Mutation (SNP) | VAF 116/148 reads (78%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV99796270; called by muse, mutect2, varscan2
- ADGRG7 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 232/488 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56299253; called by muse, mutect2, varscan2
- ADGRL2 | c.3275G>A p.R1092Q (on ENST00000370717 / NM_001366005.1; = p.R1079Q on NM_012302.4) | Missense Mutation (SNP) | VAF 211/467 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.038); catalogued as rs767737569, COSV54654551; called by muse, mutect2, varscan2
- ADGRL4 | c.1521G>A p.W507* | Nonsense Mutation (SNP) | VAF 295/664 reads (44%) | catalogued as COSV66063072; called by muse, mutect2, varscan2
- AGMAT | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 390/928 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.153); catalogued as rs1213386987; called by muse, mutect2
- AGTR2 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 241/312 reads (77%) | SIFT tolerated (0.72); PolyPhen benign (0.018); catalogued as rs138066085; called by muse, mutect2, varscan2
- AHNAK2 | c.7169C>T p.P2390L | Missense Mutation (SNP) | VAF 356/912 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs768667423; called by muse, mutect2
- AIF1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 175/815 reads (21%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.483); catalogued as COSV100559070; called by muse, mutect2, varscan2
- AIRE | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 180/501 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.164); catalogued as rs966636123, COSV52392733; called by muse, mutect2, varscan2
- AK9 | c.3319C>T p.L1107F | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58138188, COSV58141295; called by muse, mutect2, varscan2
- AK9 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370294605; called by muse, mutect2, varscan2
- AKAP11 | c.3949C>T p.P1317S | Missense Mutation (SNP) | VAF 496/755 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV99214519; called by muse, mutect2, varscan2
- AKAP6 | c.6532G>A p.E2178K | Missense Mutation (SNP) | VAF 198/534 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.395); catalogued as rs982411521; called by muse, mutect2, varscan2
- AKR1D1 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 212/505 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as rs1173927246, COSV54340322; called by muse, varscan2
- AL590132.1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 369/874 reads (42%) | SIFT tolerated, low confidence (0.38); catalogued as rs954104044; called by muse, mutect2, varscan2
- ALDH16A1 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 389/1042 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs1336722001; called by muse, mutect2, varscan2
- ALDH1A2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 248/669 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.08); catalogued as COSV99990755; called by muse, mutect2, varscan2
- ALMS1 | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 217/558 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100044087; called by muse, mutect2, varscan2
- ALPG | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 310/839 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV99779288; called by muse, mutect2, varscan2
- ALPK3 | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 627/1267 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV99362112; called by muse, mutect2, varscan2
- AMPH | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 247/644 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781682680, COSV57737654; called by muse, mutect2, varscan2
- AMY2A | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 284/709 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs148507365, COSV101340692, COSV70214788; called by muse, mutect2, varscan2
- ANGPT4 | c.581A>G p.Q194R | Missense Mutation (SNP) | VAF 207/407 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101124938; called by muse, mutect2, varscan2
- ANK1 | c.4924G>A p.E1642K | Missense Mutation (SNP) | VAF 372/859 reads (43%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs372606605, COSV55897961; called by muse, mutect2, varscan2
- ANK1 | c.4048G>A p.E1350K | Missense Mutation (SNP) | VAF 354/847 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV55885737; called by muse, mutect2, varscan2
- ANK3 | c.13105C>T p.R4369W (on ENST00000280772 / NM_001320874.2; = p.R993W on NM_001149.3) | Missense Mutation (SNP) | VAF 142/462 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs556782173, COSV55057446; called by muse, mutect2, varscan2
- ANK3 | c.9982C>T p.P3328S | Missense Mutation (SNP) | VAF 140/423 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); catalogued as rs148029765, COSV55060820; called by muse, mutect2, varscan2
- ANK3 | c.6071C>T p.S2024F | Missense Mutation (SNP) | VAF 129/316 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV55060523; called by muse, mutect2
- ANK3 | c.5384C>T p.P1795L | Missense Mutation (SNP) | VAF 162/451 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.656); catalogued as rs571449073; called by muse, mutect2, varscan2
- ANKFN1 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 184/479 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as rs750597107; called by muse, mutect2, varscan2
- ANKFN1 | c.1126G>A p.D376N | Missense Mutation (SNP) | VAF 187/495 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1483775741, COSV59457299; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7003C>T p.P2335S | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as rs1324125991; called by muse, mutect2, varscan2
- ANKRD24 | c.1225G>C p.V409L | Missense Mutation (SNP) | VAF 340/825 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV53675149; called by muse, mutect2, varscan2
- ANKRD30A | c.1294G>A p.A432T (on ENST00000611781; = p.A376T on NM_052997.2) | Missense Mutation (SNP) | VAF 132/523 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); catalogued as rs1443657019, COSV64618400; called by muse, mutect2, varscan2
- ANKRD30A | c.1521G>A p.M507I (on ENST00000611781; = p.M451I on NM_052997.2) | Missense Mutation (SNP) | VAF 142/267 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs564319804, COSV64614781; called by muse, mutect2, varscan2
- ANKRD30B | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs772268065, COSV62813891; called by muse, varscan2
- ANKRD60 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 227/400 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs899988816, COSV64518559; called by muse, varscan2
- ANO2 | c.790G>A p.E264K (on ENST00000356134 / NM_001278597.3; = p.E268K on NM_001278596.3) | Missense Mutation (SNP) | VAF 118/519 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV59047961; called by muse, mutect2, varscan2
- ANO3 | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 251/525 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.889); catalogued as rs1458612996, COSV56788908; called by muse, mutect2, varscan2
- ANO4 | c.1446G>A p.M482I (on ENST00000392977 / NM_001286615.2; = p.M447I on NM_178826.4) | Missense Mutation (SNP) | VAF 348/468 reads (74%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV54612995; called by muse, mutect2, varscan2
- ANO5 | c.1999C>T p.L667F | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.35); catalogued as COSV61086995; called by muse, mutect2, varscan2
- ANPEP | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 321/888 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs1476692994; called by muse, mutect2, varscan2
- ANPEP | c.1828G>A p.D610N | Missense Mutation (SNP) | VAF 371/809 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1456553395, COSV55589443; called by muse, mutect2, varscan2
- AP2A2 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 350/680 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100173207; called by muse, mutect2, varscan2
- APBA3 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 450/1092 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.022); catalogued as rs1225711386; called by muse, varscan2
- APC | c.4067C>T p.S1356L | Missense Mutation (SNP) | VAF 214/538 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV57325773, COSV57330189, COSV57333960; called by muse, mutect2, varscan2
- APOL1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 367/854 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs369288414; called by muse, mutect2, varscan2
- APOL3 | c.880G>A p.E294K (on ENST00000349314 / NM_145640.2; = p.E223K on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 816/948 reads (86%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV62579136; called by muse, mutect2, varscan2
- ARAP3 | c.2000C>T p.P667L | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1465420579, COSV53354616; called by muse, mutect2, varscan2
- ARHGAP26 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 202/516 reads (39%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.966); catalogued as COSV50829840; called by muse, mutect2, varscan2
- ARHGEF5 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 262/1704 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99283283; called by muse, varscan2
- ARL6IP6 | c.472A>T p.I158L | Missense Mutation (SNP) | VAF 274/680 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs182329683, COSV58444072; called by muse, mutect2, varscan2
- ARMC5 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 460/614 reads (75%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.371); catalogued as rs1467735332; called by muse, mutect2, varscan2
- ARPIN | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 341/805 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1245139234; called by muse, mutect2, varscan2
- ARSJ | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 303/413 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV59537913; called by muse, mutect2, varscan2
- ASB16 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 301/688 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs573677324; called by muse, mutect2, varscan2
- ASTN2 | c.3113G>A p.G1038E (on ENST00000313400 / NM_001365069.1; = p.G987E on NM_014010.5) | Missense Mutation (SNP) | VAF 157/443 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748277908, COSV55998169, COSV56002019; called by muse, mutect2, varscan2
- ATP11C | c.1336C>T p.Q446* | Nonsense Mutation (SNP) | VAF 164/211 reads (78%) | catalogued as COSV100557613; called by muse, mutect2, varscan2
- ATP1A3 | c.2859G>A p.K953= (on ENST00000545399 / NM_001256214.2; = p.K940= on NM_152296.5) | Splice Region (SNP) | VAF 193/560 reads (34%) | catalogued as COSV100132338; called by muse, mutect2, varscan2
- ATP4A | c.2008G>A p.D670N | Missense Mutation (SNP) | VAF 299/658 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.9); catalogued as rs1459787937, COSV52869527; called by muse, mutect2, varscan2
- ATP6V0D2 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 148/586 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV99572023; called by muse, mutect2, varscan2
- ATP8B4 | c.2885G>A p.G962E | Missense Mutation (SNP) | VAF 375/786 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52723464; called by muse, mutect2, varscan2
- AXL | c.1616G>A p.G539E (on ENST00000301178 / NM_021913.5; = p.G530E on NM_001699.6) | Missense Mutation (SNP) | VAF 317/773 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56564783; called by muse, mutect2, varscan2
- B4GALNT3 | c.2177C>T p.S726L | Missense Mutation (SNP) | VAF 222/855 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs567579470, COSV56752097; called by muse, mutect2, varscan2
- BAIAP2L1 | c.431G>T p.R144I | Missense Mutation (SNP) | VAF 298/807 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV50059341; called by muse, mutect2, varscan2
- BCAS1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 93/391 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV65090147; called by muse, mutect2, varscan2
- BCL11A | c.1007C>T p.S336F (on ENST00000335712 / NM_001365609.1; = p.S370F on NM_018014.4) | Missense Mutation (SNP) | VAF 288/624 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs984726946; called by muse, mutect2, varscan2
- BDKRB1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 265/648 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145002930, COSV53706253; called by muse, mutect2, varscan2
- BEND4 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 344/473 reads (73%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.057); catalogued as COSV101549699; called by muse, mutect2, varscan2
- BMP5 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 148/690 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV63701018; called by muse, mutect2, varscan2
- BRAF | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 211/522 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as rs397507472, COSV56068050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRIP1 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 247/573 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs146031731, CM160118; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BTG4 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 308/426 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV63637412; called by muse, mutect2, varscan2
- BTNL3 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 210/283 reads (74%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61564826; called by muse, mutect2, varscan2
- BTNL3 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 143/432 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV61564844; called by muse, mutect2, varscan2
- C10orf120 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 174/445 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs756538058, COSV100271618; called by muse, mutect2, varscan2
- C10orf71 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 140/249 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60505818; called by muse, mutect2, varscan2
- C10orf71 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 189/306 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.278); catalogued as rs1467149505, COSV100110093; called by muse, mutect2, varscan2
- C10orf71 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 184/302 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.278); catalogued as rs758980501, COSV60509997; called by muse, mutect2, varscan2
- C11orf40 | n.142G>A | Splice Region (SNP) | VAF 70/284 reads (25%) | catalogued as COSV56890552; called by muse, varscan2
- C1QTNF4 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 247/985 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs1466620981; called by muse, mutect2, varscan2
- C1R | c.1640G>A p.G547E (on ENST00000536053 / NM_001354346.2; = p.G533E on NM_001733.7) | Missense Mutation (SNP) | VAF 374/697 reads (54%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.567); catalogued as COSV73382815; called by muse, mutect2, varscan2
- C1orf94 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 363/685 reads (53%) | catalogued as rs1557475925; called by muse, mutect2, varscan2
- C20orf144 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 215/917 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs997208461; called by muse, mutect2, varscan2
- C2orf16 | c.3115G>A p.D1039N | Missense Mutation (SNP) | VAF 256/621 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs754428308, COSV62673723; called by muse, mutect2, varscan2
- C2orf81 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 246/637 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs1225754891; called by muse, mutect2, varscan2
- C3orf20 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 276/646 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs1166049309; called by muse, mutect2
- C6 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 167/847 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV99667795; called by muse, mutect2, varscan2
- C7 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 208/360 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs977493333, COSV57471713; called by muse, varscan2
- C8A | c.1393C>T p.H465Y | Missense Mutation (SNP) | VAF 240/624 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs1483234568, COSV63484731; called by muse, mutect2, varscan2
- C8B | c.90C>T p.S30= | Splice Region (SNP) | VAF 228/533 reads (43%) | catalogued as rs758163769; called by muse, varscan2
- CACNA1E | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 130/543 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62391236; called by muse, mutect2, varscan2
- CACNA1F | c.5510C>T p.S1837F | Missense Mutation (SNP) | VAF 272/318 reads (86%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV59904536; called by muse, mutect2, varscan2
- CACNA1S | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 143/565 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62936125; called by muse, mutect2, varscan2
- CADPS2 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 189/475 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs773480913, COSV57351573; called by muse, mutect2, varscan2
- CALHM3 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 177/520 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.809); catalogued as rs751696710; called by muse, mutect2, varscan2
- CAP2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 119/547 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs762449193; called by muse, mutect2, varscan2
- CAPN13 | c.1961G>A p.G654E | Missense Mutation (SNP) | VAF 260/616 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs558380156, COSV54431295; called by muse, varscan2
- CAPN3 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 232/666 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV58820789; called by muse, mutect2, varscan2
- CARNS1 | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 509/1261 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs749238189, COSV100322225; called by muse, mutect2, varscan2
- CATSPER2 | c.1486C>T p.R496* (on ENST00000321596 / NM_001282309.3; = p.R498* on NM_172095.4) | Nonsense Mutation (SNP) | VAF 423/1252 reads (34%) | catalogued as rs377026307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CATSPERB | c.3010C>T p.L1004F | Missense Mutation (SNP) | VAF 124/372 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV56422881; called by muse, mutect2, varscan2
- CBX2 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 423/999 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1428652993; called by muse, mutect2, varscan2
- CCDC105 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 227/607 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); catalogued as COSV52963394; called by muse, mutect2, varscan2
- CCDC141 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 214/516 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs747242213, COSV55382394; called by muse, varscan2
- CCDC190 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 336/750 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV63362763; called by muse, varscan2
- CCDC73 | c.315G>A p.K105= | Splice Region (SNP) | VAF 58/294 reads (20%) | catalogued as COSV58799502; called by muse, mutect2
- CCDC88C | c.3629G>A p.G1210E | Missense Mutation (SNP) | VAF 141/315 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101105505; called by muse, mutect2, varscan2
- CCR9 | c.384G>A p.M128I (on ENST00000357632 / NM_031200.3; = p.M116I on NM_006641.4) | Missense Mutation (SNP) | VAF 266/505 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV62940607; called by muse, mutect2, varscan2
- CD101 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 318/753 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1053045019; called by muse, mutect2, varscan2
- CD163 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 302/576 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63131336; called by muse, varscan2
- CD1E | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 122/561 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as COSV63770627; called by muse, mutect2, varscan2
- CD22 | c.2081C>T p.S694F | Missense Mutation (SNP) | VAF 292/684 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1298147775; called by muse, mutect2, varscan2
- CD27 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 145/586 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV56950184; called by muse, mutect2, varscan2
- CD38 | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 250/331 reads (76%) | SIFT tolerated (0.1); PolyPhen benign (0.176); catalogued as COSV56889215; called by muse, mutect2, varscan2
- CD5L | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 273/544 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.202); catalogued as rs1350559311; called by muse, mutect2, varscan2
- CDC123 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); catalogued as rs1353855260; called by muse, mutect2, varscan2
- CDC42BPG | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 190/642 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867829277; called by muse, mutect2, varscan2
- CDH12 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 403/686 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs770584780, COSV66385717; called by muse, mutect2, varscan2
- CDH13 | c.1513G>A p.D505N | Missense Mutation (SNP) | VAF 308/388 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774928488; called by muse, mutect2, varscan2
- CDH17 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 242/424 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755346799; called by muse, mutect2
- CDH18 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 163/721 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99933587; called by muse, mutect2, varscan2
- CDH23 | c.3843G>A p.M1281I | Missense Mutation (SNP) | VAF 191/487 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV99823575; called by muse, mutect2, varscan2
- CDH23 | c.7138C>T p.P2380S | Missense Mutation (SNP) | VAF 218/566 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99823332; called by muse, mutect2, varscan2
- CDH26 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 158/675 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV54842958; called by muse, mutect2, varscan2
- CDH4 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 201/837 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV64641612, COSV64643972; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 243/428 reads (57%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDHR2 | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 164/463 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99990842; called by muse, mutect2, varscan2
- CEACAM20 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 304/750 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.465); catalogued as COSV57603041; called by muse, mutect2, varscan2
- CELSR1 | c.4925C>T p.T1642I | Missense Mutation (SNP) | VAF 243/583 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1288070949; called by muse, mutect2, varscan2
- CELSR2 | c.7913C>T p.S2638F | Missense Mutation (SNP) | VAF 286/707 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV54766536; called by muse, mutect2, varscan2
- CFAP221 | c.2182C>T p.L728F | Missense Mutation (SNP) | VAF 252/602 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.184); catalogued as rs1429107163; called by muse, mutect2, varscan2
- CFAP46 | c.922A>G p.I308V | Missense Mutation (SNP) | VAF 145/432 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.071); catalogued as COSV63953759; called by muse, mutect2, varscan2
- CFAP74 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 280/683 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs1420420512; called by muse, mutect2, varscan2
- CFAP94 | c.1798G>A p.A600T (on ENST00000320267 / NM_001352064.2; = p.A606T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 268/362 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57230325; called by muse, mutect2, varscan2
- CFB | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 210/957 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as rs1291066881; called by muse, mutect2, varscan2
- CFTR | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 286/745 reads (38%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as rs397508822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CFTR | c.3890C>T p.S1297F | Missense Mutation (SNP) | VAF 159/407 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50055472; called by muse, mutect2, varscan2
- CGNL1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 201/577 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs748686101, COSV55570841; called by muse, mutect2, varscan2
- CHD3 | c.4972G>A p.G1658R (on ENST00000330494 / NM_001005273.3; = p.G1717R on NM_001005271.3) | Missense Mutation (SNP) | VAF 270/346 reads (78%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1248242661; called by muse, mutect2, varscan2
- CHD5 | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 373/944 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52412020; called by muse, mutect2, varscan2
- CHD7 | c.3550C>T p.P1184S | Missense Mutation (SNP) | VAF 185/374 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1405371608; called by muse, mutect2, varscan2
- CHD7 | c.5623C>T p.P1875S | Missense Mutation (SNP) | VAF 262/503 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs762351985, COSV71108182; called by muse, mutect2, varscan2
- CHD8 | c.3337C>T p.R1113C (on ENST00000646647 / NM_001170629.2; = p.R834C on NM_020920.4) | Missense Mutation (SNP) | VAF 137/362 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs749785996; called by muse, mutect2, varscan2
- CHGB | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 200/692 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV99081176; called by muse, mutect2, varscan2
- CHL1 | c.1313G>A p.G438E (on ENST00000397491 / NM_001253387.1; = p.G454E on NM_006614.4) | Missense Mutation (SNP) | VAF 126/491 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV56606743; called by muse, mutect2, varscan2
- CHPF2 | c.787C>T p.L263F | Missense Mutation (SNP) | VAF 264/743 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs1291202356; called by muse, mutect2, varscan2
- CIB2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 401/1190 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as rs780146135; called by muse, mutect2, varscan2
- CILP | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 237/689 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201483229; called by muse, mutect2, varscan2
- CLCN1 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 218/550 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58373130; called by muse, varscan2
- CLDN6 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 153/757 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58509216; called by muse, mutect2, varscan2
- CLEC3A | c.205G>A p.E69K (on ENST00000651443; = p.E60K on NM_005752.6) | Missense Mutation (SNP) | VAF 316/427 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55219916; called by muse, mutect2, varscan2
- CLSTN3 | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 177/694 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs755463631; called by muse, mutect2, varscan2
- CNGB3 | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 218/405 reads (54%) | SIFT tolerated (0.8); PolyPhen benign (0.066); catalogued as COSV60699177; called by muse, mutect2, varscan2
- CNGB3 | c.2051G>A p.G684E | Missense Mutation (SNP) | VAF 148/510 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as rs759584325; called by muse, mutect2, varscan2
- CNR2 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 328/647 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770828039; called by muse, mutect2, varscan2
- CNTN4 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 259/484 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); catalogued as rs750294828, COSV61873461; called by muse, mutect2, varscan2
- CNTN5 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 205/295 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54285848; called by muse, mutect2, varscan2
- CNTNAP2 | c.1058G>T p.R353M | Missense Mutation (SNP) | VAF 232/554 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100665319, COSV62202488; called by muse, mutect2, varscan2
- CNTNAP4 | c.3026C>T p.S1009F | Missense Mutation (SNP) | VAF 132/185 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56702461; called by muse, mutect2, varscan2
- COL11A1 | c.2261G>A p.G754D | Missense Mutation (SNP) | VAF 286/670 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100616110; called by muse, mutect2, varscan2
- COL11A2 | c.2272G>A p.E758K (on ENST00000341947 / NM_080680.3; = p.E651K on NM_080679.2) | Missense Mutation (SNP) | VAF 243/701 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1304713056, COSV59499234; called by muse, mutect2, varscan2
- COL12A1 | c.2921C>T p.S974L | Missense Mutation (SNP) | VAF 158/465 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1308564004, COSV59395583; called by muse, mutect2, varscan2
- COL14A1 | c.5303G>A p.G1768D | Missense Mutation (SNP) | VAF 106/407 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as COSV52865798; called by muse, mutect2, varscan2
- COL16A1 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 238/791 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54713244; called by muse, mutect2, varscan2
- COL17A1 | c.465G>A p.W155* | Nonsense Mutation (SNP) | VAF 119/310 reads (38%) | catalogued as rs1228451285; called by muse, mutect2, varscan2
- COL19A1 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 86/271 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs765477557; called by muse, mutect2, varscan2
- COL19A1 | c.3302C>T p.A1101V | Missense Mutation (SNP) | VAF 88/228 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs753501507, COSV59577484; called by muse, mutect2, varscan2
- COL1A2 | c.733C>T p.P245S | Missense Mutation (SNP) | VAF 252/623 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); catalogued as COSV51960202; called by muse, varscan2
- COL21A1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 124/392 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs368730001; called by muse, varscan2
- COL22A1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 238/852 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249474608; called by muse, mutect2, varscan2
- COL24A1 | c.3862G>A p.G1288R | Missense Mutation (SNP) | VAF 214/529 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768681059; called by muse, mutect2, varscan2
- COL3A1 | c.326G>A p.G109E | Missense Mutation (SNP) | VAF 200/520 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58581677; called by muse, mutect2, varscan2
- COL3A1 | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 249/609 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV58596953; called by muse, mutect2, varscan2
- COL3A1 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 197/494 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58582876; called by muse, mutect2, varscan2
- COL3A1 | c.3532C>T p.P1178S | Missense Mutation (SNP) | VAF 213/553 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.106); catalogued as rs759565407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 535/752 reads (71%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.936); catalogued as rs1402878630, COSV101011106; called by muse, mutect2, varscan2
- COL4A4 | c.3605C>T p.P1202L | Missense Mutation (SNP) | VAF 238/699 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.419); catalogued as rs779182761; called by muse, mutect2, varscan2
- COL4A5 | c.2200G>A p.G734S | Missense Mutation (SNP) | VAF 163/219 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs867265684; called by muse, mutect2, varscan2
- COL5A3 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 390/883 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs771247699; called by muse, mutect2, varscan2
- COL6A3 | c.7627C>T p.L2543F | Missense Mutation (SNP) | VAF 315/780 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99796317; called by muse, mutect2
- COL7A1 | c.6016G>A p.G2006S | Missense Mutation (SNP) | VAF 274/1023 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034798; called by muse, mutect2, varscan2
- COL7A1 | c.5710G>A p.G1904S | Missense Mutation (SNP) | VAF 461/822 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1357729432; called by muse, mutect2, varscan2
- COL9A1 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 127/342 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1464239976, COSV61831024; called by muse, mutect2, varscan2
- COL9A3 | c.1700C>T p.P567L | Missense Mutation (SNP) | VAF 597/1077 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs748114912; called by muse, mutect2, varscan2
- COQ8A | c.946C>T p.L316F | Missense Mutation (SNP) | VAF 430/699 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV64657571; called by muse, mutect2, varscan2
- CORO7 | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 142/598 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1372322168; called by muse, mutect2, varscan2
- CPNE9 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 173/618 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as COSV56069323; called by muse, mutect2, varscan2
- CPOX | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 194/694 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.018); catalogued as rs938112157; called by muse, mutect2, varscan2
- CRYBG1 | c.4801G>A p.D1601N | Missense Mutation (SNP) | VAF 150/432 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.041); catalogued as COSV64815014; called by muse, mutect2, varscan2
- CRYBG1 | c.5417C>T p.S1806F | Missense Mutation (SNP) | VAF 94/260 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64811836; called by muse, mutect2, varscan2
- CSMD2 | c.4561C>T p.P1521S | Missense Mutation (SNP) | VAF 390/778 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53966299; called by muse, mutect2, varscan2
- CSMD2 | c.1195G>A p.V399I | Missense Mutation (SNP) | VAF 220/472 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as rs1350135389; called by muse, mutect2
- CSMD2 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 127/547 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53922489; called by muse, mutect2, varscan2
- CSMD3 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 133/484 reads (27%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.999); catalogued as COSV52155228, COSV52161078; called by muse, mutect2, varscan2
- CSPG4 | c.3566A>T p.Q1189L | Missense Mutation (SNP) | VAF 414/1055 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs760737016; called by muse, mutect2, varscan2
- CSRNP1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 308/584 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as rs150285879, COSV56189255; called by muse, varscan2
- CT55 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 103/152 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV52278577; called by muse, mutect2, varscan2
- CTAGE1 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 323/417 reads (77%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as COSV101194676; called by muse, mutect2, varscan2
- CTCFL | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 321/584 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1187038024; called by muse, varscan2
- CTNNB1 | c.2119C>T p.L707F | Missense Mutation (SNP) | VAF 254/487 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.137); catalogued as rs770804258, COSV100846071; called by muse, mutect2, varscan2
- CTSS | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 119/529 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs764417853, COSV64566046; called by muse, mutect2, varscan2
- CUX2 | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 443/788 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55646639; called by muse, varscan2
- CUX2 | c.3979C>T p.P1327S | Missense Mutation (SNP) | VAF 204/818 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs1427959865, COSV99921165; called by muse, varscan2
- CWC27 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 91/264 reads (34%) | catalogued as rs747744168, COSV66885021; called by muse, mutect2, varscan2
- CYB5R4 | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 106/280 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.394); catalogued as rs531779325, COSV63752383; called by muse, mutect2, varscan2
- CYP19A1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 236/482 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53057841; called by muse, mutect2, varscan2
- CYP2F1 | c.358C>T p.R120* | Nonsense Mutation (SNP) | VAF 170/438 reads (39%) | catalogued as rs1349532357, COSV58527253; called by muse, mutect2, varscan2
- CYP3A5 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 151/363 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV56118310; called by muse, mutect2, varscan2
- CYP4B1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 338/860 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.955); catalogued as COSV54722954; called by muse, mutect2, varscan2
- CYP4F11 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 264/630 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs1182851073; called by muse, mutect2, varscan2
- CYP4F3 | c.406C>T p.L136F | Missense Mutation (SNP) | VAF 259/651 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763337637; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 188/496 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- CYTIP | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 323/782 reads (41%) | catalogued as rs371815413, COSV51633532; called by muse, mutect2, varscan2
- DAB2IP | c.215C>T p.P72L (on ENST00000408936; = p.P44L on NM_032552.3) | Missense Mutation (SNP) | VAF 161/456 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs763394734; called by muse, mutect2, varscan2
- DBF4B | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 523/1217 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs770361509, COSV59261012; called by muse, mutect2, varscan2
- DBNL | c.1129C>T p.R377C (on ENST00000448521 / NM_001014436.3; = p.R378C on NM_014063.7) | Missense Mutation (SNP) | VAF 336/800 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1307332395, COSV99803898; called by muse, mutect2, varscan2
- DBX2 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 277/677 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375287819, COSV60339154; called by muse, mutect2, varscan2
- DCAF8L2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 314/380 reads (83%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.486); catalogued as COSV70548057; called by mutect2, varscan2
- DCC | c.1805A>T p.N602I | Missense Mutation (SNP) | VAF 156/247 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59115942; called by muse, mutect2, varscan2
- DCHS1 | c.6869T>C p.L2290S | Missense Mutation (SNP) | VAF 124/508 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV55043155; called by muse, mutect2, varscan2
- DDIAS | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 134/499 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs561618895; called by muse, varscan2
- DDX24 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 188/523 reads (36%) | catalogued as COSV100427973; called by muse, mutect2, varscan2
- DDX60 | c.1652C>T p.S551L | Missense Mutation (SNP) | VAF 277/376 reads (74%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs761677522, COSV67096562; called by muse, mutect2, varscan2
- DDX60 | c.524C>T p.S175F | Missense Mutation (SNP) | VAF 338/461 reads (73%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV67099548; called by muse, mutect2, varscan2
- DEFB115 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 229/421 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs755655392; called by muse, mutect2, varscan2
- DENND4C | c.430C>G p.R144G | Missense Mutation (SNP) | VAF 200/313 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405706072; called by muse, mutect2, varscan2
- DLGAP3 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 284/1037 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV52392177; called by muse, mutect2, varscan2
- DMRTA1 | c.803C>T p.S268L | Missense Mutation (SNP) | VAF 201/290 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.251); catalogued as COSV100364867; called by muse, mutect2, varscan2
- DNAH10 | c.4676C>T p.S1559L (on ENST00000409039; = p.S1498L on NM_207437.3) | Missense Mutation (SNP) | VAF 275/375 reads (73%) | SIFT tolerated (0.51); PolyPhen benign (0.033); catalogued as rs762069342; called by muse, mutect2, varscan2
- DNAH17 | c.11035C>T p.L3679F | Missense Mutation (SNP) | VAF 257/657 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780519831; called by muse, mutect2, varscan2
- DNAH17 | c.8059G>A p.E2687K | Missense Mutation (SNP) | VAF 358/826 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748291573; called by muse, mutect2, varscan2
- DNAH5 | c.11329G>A p.E3777K | Missense Mutation (SNP) | VAF 365/656 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201213490; called by muse, mutect2, varscan2
- DNAH5 | c.8627G>A p.R2876K | Missense Mutation (SNP) | VAF 145/583 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV54221519; called by muse, mutect2, varscan2
- DNAH5 | c.5833G>A p.E1945K | Missense Mutation (SNP) | VAF 132/571 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54223692; called by muse, mutect2, varscan2
- DNAH5 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 99/494 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as rs868197877; called by muse, mutect2, varscan2
- DNAH6 | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 152/409 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs111548143, COSV52877008; called by muse, mutect2, varscan2
- DNAH7 | c.11419C>T p.Q3807* | Nonsense Mutation (SNP) | VAF 161/426 reads (38%) | catalogued as rs867446312, COSV100414139, COSV56761586, COSV56774674; called by muse, mutect2, varscan2
- DNAH7 | c.5657G>A p.R1886Q | Missense Mutation (SNP) | VAF 232/582 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs13034775; called by muse, mutect2, varscan2
- DNAH8 | c.3397G>A p.E1133K | Missense Mutation (SNP) | VAF 80/421 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1296329386; called by muse, mutect2, varscan2
- DNAH8 | c.9406G>A p.E3136K | Missense Mutation (SNP) | VAF 148/663 reads (22%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.491); catalogued as COSV59434212; called by muse, mutect2, varscan2
- DNAH8 | c.12220C>T p.P4074S | Missense Mutation (SNP) | VAF 139/642 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601021, COSV59448034; called by muse, mutect2, varscan2
- DNAI3 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 194/493 reads (39%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.539); catalogued as COSV54000327; called by muse, mutect2, varscan2
- DNAI3 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 194/492 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV54002387; called by muse, mutect2, varscan2
- DNAJC5B | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 229/442 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0.041); catalogued as rs141686243, COSV52535470; called by muse, mutect2, varscan2
- DNASE1L3 | c.546G>A p.E182= | Splice Region (SNP) | VAF 211/457 reads (46%) | catalogued as rs1201586524; called by muse, mutect2, varscan2
- DNER | c.1403T>C p.L468P | Missense Mutation (SNP) | VAF 383/821 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV59160080; called by muse, mutect2, varscan2
- DNM3 | c.1714C>T p.P572S (on ENST00000355305 / NM_001350206.2; = p.P562S on NM_015569.5) | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs752381838; called by muse, mutect2, varscan2
- DNTTIP2 | c.103C>A p.P35T | Missense Mutation (SNP) | VAF 178/500 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as rs776402469; called by muse, mutect2, varscan2
- DOCK10 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 286/705 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1224011972; called by muse, mutect2, varscan2
- DOCK3 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 373/743 reads (50%) | catalogued as COSV99810460; called by muse, mutect2, varscan2
- DOCK3 | c.2954G>A p.R985Q | Missense Mutation (SNP) | VAF 271/546 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1302203796; called by muse, varscan2
- DOCK3 | c.4207C>T p.P1403S | Missense Mutation (SNP) | VAF 176/648 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.044); catalogued as rs1422888538; called by muse, mutect2, varscan2
- DOCK4 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 369/876 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1421882969, COSV70234917; called by muse, mutect2, varscan2
- DOP1B | c.5804C>T p.P1935L | Missense Mutation (SNP) | VAF 105/338 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101215050; called by muse, mutect2, varscan2
- DOT1L | c.3028C>T p.P1010S | Missense Mutation (SNP) | VAF 541/1207 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as rs781640234; called by muse, mutect2, varscan2
- DPP6 | c.253G>A p.G85R (on ENST00000377770 / NM_001364500.2; = p.G23R on NM_001936.5) | Missense Mutation (SNP) | VAF 208/504 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100122333, COSV100127589; called by muse, mutect2, varscan2
- DSP | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 228/681 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1060500620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSTYK | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 335/881 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1423121390; called by muse, mutect2, varscan2
- DUSP11 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 129/332 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as rs1558534864; called by muse, mutect2, varscan2
- DYRK3 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 380/897 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1553420740; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 334/606 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779182481; called by muse, mutect2, varscan2
- EEF1AKMT1 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 318/657 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs772597833; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 238/590 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1270644579; called by muse, mutect2, varscan2
- EEF1AKNMT | c.2016G>T p.L672F (on ENST00000361735 / NM_015935.5; = p.L586F on NM_014955.3) | Missense Mutation (SNP) | VAF 339/623 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100676049; called by muse, mutect2, varscan2
- EEF2K | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 355/467 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as rs1219770042, COSV99532611; called by muse, mutect2, varscan2
- EFCAB8 | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 110/561 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as rs1354026107; called by muse, varscan2
- EFHC1 | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 106/554 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV64137649; called by muse, mutect2, varscan2
- EGFLAM | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 348/599 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1461002865, COSV100380490; called by muse, mutect2, varscan2
- EHD2 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 497/1148 reads (43%) | catalogued as COSV99621944; called by muse, mutect2, varscan2
- EHD3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 257/606 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59031720; called by muse, mutect2, varscan2
- EIF4G3 | c.2276G>A p.R759Q | Missense Mutation (SNP) | VAF 197/370 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as rs950216111, COSV51690121; called by muse, mutect2, varscan2
- ELANE | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 424/954 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.728); catalogued as rs1555709342, COSV52256455; ClinVar: uncertain significance; called by muse, varscan2
- ELAPOR2 | c.2521C>T p.P841S (on ENST00000450689 / NM_001142749.3; = p.P674S on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 292/709 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51884556; called by muse, mutect2, varscan2
- ELOA | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 105/375 reads (28%) | catalogued as rs1225403142; called by muse, mutect2, varscan2
- ELP3 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 335/798 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs749474343, COSV56459999; called by muse, mutect2, varscan2
- ELP4 | c.697C>T p.Q233* (on ENST00000350638; = p.Q232* on NM_019040.5) | Nonsense Mutation (SNP) | VAF 226/422 reads (54%) | catalogued as rs1357038410; called by muse, mutect2, varscan2
- EML3 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 285/546 reads (52%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as rs767044881; called by muse, mutect2, varscan2
- EML5 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 124/382 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs773834442, COSV61352259; called by muse, mutect2, varscan2
- ENPP4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 156/708 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as COSV58088221, COSV58088735; called by muse, mutect2, varscan2
- ENTPD7 | c.781G>A p.G261R | Missense Mutation (SNP) | VAF 212/577 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748202130; called by muse, mutect2
- EPB41L4A | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs774150056, COSV99079267; called by muse, mutect2, varscan2
- EPHA2 | c.1132C>T p.P378S | Missense Mutation (SNP) | VAF 475/1079 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100626198; called by muse, mutect2, varscan2
- EPHA7 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1562049937; called by muse, mutect2, varscan2
- EPHB2 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 239/838 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1215107970; called by muse, mutect2, varscan2
- EPN2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 210/292 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59060580; called by muse, mutect2, varscan2
- EPYC | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 280/554 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754135032, COSV53798497; called by muse, mutect2, varscan2
- ERBB4 | c.3559G>A p.E1187K | Missense Mutation (SNP) | VAF 344/816 reads (42%) | SIFT tolerated (0.88); PolyPhen benign (0.06); catalogued as rs144842611, COSV61506927; called by muse, mutect2, varscan2
- ERC2 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 292/534 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as rs780698592, COSV55672206; called by muse, mutect2, varscan2
- ERICH3 | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 268/719 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.168); catalogued as COSV58602480; called by muse, mutect2, varscan2
- ERICH6 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 342/451 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV55799220; called by muse, mutect2, varscan2
- ERN2 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 294/384 reads (77%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as rs887550309; called by muse, mutect2, varscan2
- ERVFRD-1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 250/557 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.098); catalogued as rs766557849, COSV65368584; called by muse, mutect2, varscan2
- ESPL1 | c.1934C>T p.T645I | Missense Mutation (SNP) | VAF 208/267 reads (78%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV57757367; called by muse, mutect2, varscan2
- ESR1 | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 209/503 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52781079; called by muse, mutect2, varscan2
- ESR1 | c.1174G>C p.V392L | Missense Mutation (SNP) | VAF 173/409 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV52782387; called by muse, mutect2, varscan2
- ETV6 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 346/561 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV67150057, COSV67152262; called by muse, mutect2, varscan2
- EVPL | c.4645G>A p.A1549T | Missense Mutation (SNP) | VAF 596/1363 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100044431; called by muse, mutect2, varscan2
- EVPL | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 509/1107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767324618, COSV56908538; called by muse, mutect2, varscan2
- EXD1 | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 168/613 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as rs374507380; called by muse, mutect2, varscan2
- EXOC6B | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 289/730 reads (40%) | catalogued as rs369498012; called by muse, mutect2, varscan2
- EXPH5 | c.3376C>T p.P1126S | Missense Mutation (SNP) | VAF 328/462 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1442229862; called by muse, mutect2, varscan2
- EYS | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 171/448 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs907697038; called by muse, mutect2, varscan2
- FAM13C | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 113/379 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV53246271; called by muse, mutect2, varscan2
- FAM166C | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 533/1239 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.099); catalogued as rs1285725550, COSV61594074; called by muse, mutect2, varscan2
- FAM171A1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 256/533 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs1454149720, COSV100968479; called by muse, mutect2, varscan2
- FAM189B | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 410/916 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs763340243; called by muse, mutect2, varscan2
- FAM214A | c.1336C>T p.R446* | Nonsense Mutation (SNP) | VAF 151/935 reads (16%) | catalogued as rs200373322, COSV55922249; called by muse, mutect2, varscan2
- FAM221B | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs267602231, COSV100941219; called by muse, mutect2, varscan2
- FAM83H | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 323/1009 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); catalogued as rs1554624115; called by muse, mutect2, varscan2
- FARS2 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 113/536 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51165307; called by muse, mutect2, varscan2
- FAT4 | c.10031G>A p.R3344Q | Missense Mutation (SNP) | VAF 292/389 reads (75%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs769028469, COSV58676528; called by muse, mutect2, varscan2
- FAT4 | c.13697C>T p.P4566L | Missense Mutation (SNP) | VAF 338/467 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as COSV58674970; called by muse, mutect2, varscan2
- FBH1 | c.1142C>T p.T381I (on ENST00000362091 / NM_178150.3; = p.T432I on NM_032807.4) | Missense Mutation (SNP) | VAF 352/665 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); catalogued as rs1340597635; called by muse, mutect2, varscan2
- FBH1 | c.1220A>G p.Y407C (on ENST00000362091 / NM_178150.3; = p.Y458C on NM_032807.4) | Missense Mutation (SNP) | VAF 159/302 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs912547395; called by muse, mutect2, varscan2
- FBN1 | c.4352C>T p.S1451F | Missense Mutation (SNP) | VAF 103/649 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100354139; called by muse, mutect2, varscan2
- FBN3 | c.5794G>A p.E1932K | Missense Mutation (SNP) | VAF 188/439 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54456058; called by muse, mutect2, varscan2
- FBXO40 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 409/901 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV57527104; called by muse, mutect2, varscan2
- FCAMR | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 331/776 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as rs865944502; called by muse, mutect2, varscan2
- FCGR1A | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 336/868 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1161084692, COSV100977284; called by muse, mutect2, varscan2
- FCRL3 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 311/561 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as rs746762170; called by muse, mutect2, varscan2
- FCRL6 | c.1180-1G>A p.X394_splice | Splice Site (SNP) | VAF 330/565 reads (58%) | catalogued as rs749199087; called by muse, mutect2
- FER1L6 | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 278/545 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.8); catalogued as COSV67549766; called by muse, mutect2, varscan2
- FFAR1 | c.35A>G p.Y12C | Missense Mutation (SNP) | VAF 403/898 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1272926150; called by muse, mutect2, varscan2
- FGF4 | c.343C>T p.L115= | Splice Region (SNP) | VAF 149/595 reads (25%) | catalogued as COSV51449277; called by muse, mutect2, varscan2
- FGFBP1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 314/414 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52587320; called by muse, mutect2, varscan2
- FGFR1 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 416/1133 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.261); catalogued as rs200116660; called by muse, mutect2, varscan2
- FGFR2 | c.1274G>A p.R425Q | Missense Mutation (SNP) | VAF 122/344 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs998662110, COSV60643939; called by muse, mutect2, varscan2
- FHL5 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58739365; called by muse, mutect2, varscan2
- FKBP15 | c.2293C>T p.R765C | Missense Mutation (SNP) | VAF 175/420 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1418288662; called by muse, mutect2, varscan2
- FLG | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 274/715 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.367); catalogued as rs1228611224, COSV64242219; called by muse, mutect2, varscan2
- FLT1 | c.1708G>A p.G570R | Missense Mutation (SNP) | VAF 161/903 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99164223; called by muse, mutect2, varscan2
- FLT1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 141/784 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV56728011; called by muse, mutect2, varscan2
- FMN2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 157/650 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60420267; called by muse, mutect2, varscan2
- FMO3 | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 372/640 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs1353702156, COSV63008662; called by muse, mutect2, varscan2
- FMR1NB | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 162/212 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV63272717; called by muse, mutect2, varscan2
- FNDC1 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 100/269 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51949627; called by muse, mutect2, varscan2
- FNDC1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 136/410 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as rs370527562; called by muse, mutect2, varscan2
- FNDC3B | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 385/905 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs762528973; called by muse, mutect2, varscan2
- FOLR1 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 306/576 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0.038); catalogued as COSV56616329; called by muse, mutect2, varscan2
- FOXG1 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 139/340 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV57396312; called by muse, mutect2, varscan2
- FOXN1 | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 300/401 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56883377; called by muse, mutect2, varscan2
- FPR3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 269/708 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as rs779072888, COSV59331000; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 135/732 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by muse, mutect2, varscan2
- FREM2 | c.6157C>T p.P2053S | Missense Mutation (SNP) | VAF 421/557 reads (76%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as rs767742573; called by muse, mutect2, varscan2
- FRMD3 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 166/654 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.23); catalogued as COSV58472547; called by muse, mutect2, varscan2
- FTCD | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 181/512 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs775567630; called by muse, mutect2, varscan2
- FUT3 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 376/1494 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV99744937; called by muse, varscan2
- FUT8 | c.1322G>A p.R441Q (on ENST00000360689 / NM_001371534.1; = p.R278Q on NM_004480.4) | Missense Mutation (SNP) | VAF 142/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs758856033, COSV61290251; called by muse, mutect2, varscan2
- FYB2 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 147/370 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs749801475; called by muse, mutect2, varscan2
- FZD7 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 393/910 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV53808730; called by muse, mutect2, varscan2
- G3BP2 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 211/283 reads (75%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV62975713; called by muse, mutect2, varscan2
- GAB3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 255/333 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65818942, COSV65820626; called by muse, mutect2, varscan2
- GABRB2 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs150956270, COSV50906276; called by muse, mutect2, varscan2
- GALNT14 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 295/720 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as rs373408955; called by muse, mutect2, varscan2
- GALNT17 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 204/510 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773651456, COSV61160937; called by muse, mutect2, varscan2
- GAPVD1 | c.2780G>A p.R927Q (on ENST00000394104; = p.R954Q on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 194/493 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.921); catalogued as rs1190889306; called by muse, mutect2, varscan2
- GET3 | c.619A>C p.M207L | Missense Mutation (SNP) | VAF 284/651 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV100628239; called by muse, mutect2, varscan2
- GIMAP4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 252/632 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV55434967; called by muse, mutect2, varscan2
- GIMAP8 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 349/860 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1165066384, COSV56230314; called by muse, mutect2, varscan2
- GLB1 | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 138/5854 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867088810; called by muse, mutect2
- GLRA2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 258/309 reads (83%) | SIFT tolerated (0.45); PolyPhen benign (0.131); catalogued as COSV54344147; called by muse, mutect2, varscan2
- GLYATL1 | c.291G>A p.W97* (on ENST00000317391 / NM_001354699.1; = p.W128* on NM_080661.4) | Nonsense Mutation (SNP) | VAF 58/302 reads (19%) | catalogued as rs1297270806; called by muse, mutect2, varscan2
- GLYATL3 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 159/422 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as rs1018824721, COSV100966325; called by muse, mutect2, varscan2
- GNAL | c.618C>T p.F206= (on ENST00000269162 / NM_001142339.3; = p.F283= on NM_182978.4) | Splice Region (SNP) | VAF 96/282 reads (34%) | catalogued as COSV52326254, COSV99304042; called by muse, mutect2, varscan2
- GNAS | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 217/842 reads (26%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1302332433, COSV58333722; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 509/1723 reads (30%) | SIFT deleterious, low confidence (0.01); catalogued as rs1295580440; called by muse, mutect2, varscan2
- GOLGA6L2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 164/610 reads (27%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.428); catalogued as rs774878575, COSV61478240; called by muse, mutect2, varscan2
- GPA33 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 207/473 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV63302188; called by muse, mutect2, varscan2
- GPAT2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 220/861 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64003173; called by muse, mutect2, varscan2
- GPN1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 352/830 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs1415858850, COSV53114795; called by muse, mutect2, varscan2
- GPR161 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 382/936 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs775719346, COSV54790780; called by muse, mutect2, varscan2
- GPR45 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 367/850 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51523913; called by muse, mutect2, varscan2
- GPRIN1 | c.607C>T p.P203S | Missense Mutation (SNP) | VAF 169/456 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.164); catalogued as rs549297346, COSV56136594; called by muse, mutect2, varscan2
- GPRIN2 | c.717_718insAAGATGAGG p.R239_E240insKMR | In Frame Ins (INS) | VAF 87/406 reads (21%) | catalogued as rs1345854053; called by mutect2, varscan2
- GRHL2 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 145/569 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52549020; called by muse, mutect2, varscan2
- GRHPR | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 148/422 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs764111479, COSV58944536; called by muse, varscan2
- GRIA2 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 288/385 reads (75%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.998); catalogued as rs201867927, COSV52396761; called by muse, mutect2, varscan2
- GRIN1 | c.2681G>A p.R894H | Missense Mutation (SNP) | VAF 134/361 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV59293333; called by muse, mutect2, varscan2
- GRIN2A | c.4381G>A p.E1461K | Missense Mutation (SNP) | VAF 247/331 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1555481892, COSV58025645; called by muse, mutect2, varscan2
- GRIN3A | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 219/794 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as rs112914306; called by muse, mutect2, varscan2
- GRM8 | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 275/701 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58825161; called by muse, mutect2, varscan2
- GRWD1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 222/664 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs771758365; called by muse, mutect2, varscan2
- GTF2E1 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 374/888 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV52206473, COSV99382067; called by muse, mutect2, varscan2
- GUCA1C | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 264/519 reads (51%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0); catalogued as rs1215597864, COSV53755071; called by muse, mutect2, varscan2
- H2AC1 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 182/841 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV51236684; called by muse, mutect2, varscan2
- H2BC8 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 188/527 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.819); catalogued as rs1561989055; called by muse, mutect2, varscan2
- HABP2 | c.1647G>A p.W549* | Nonsense Mutation (SNP) | VAF 146/392 reads (37%) | catalogued as COSV63491040; called by muse, varscan2
- HCRTR2 | c.1156G>C p.V386L | Missense Mutation (SNP) | VAF 163/755 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs375477231; called by muse, mutect2, varscan2
- HDC | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 148/768 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs867414908, COSV51081078; called by muse, mutect2, varscan2
- HEATR1 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 100/393 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63983008; called by muse, mutect2, varscan2
- HERC1 | c.7310C>T p.A2437V | Missense Mutation (SNP) | VAF 300/731 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs775464349; called by muse, mutect2, varscan2
- HEYL | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 235/670 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV65721530; called by muse, mutect2, varscan2
- HEYL | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 234/673 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV65722116; called by muse, mutect2, varscan2
- HIVEP3 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 392/901 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.219); catalogued as rs1213224750; called by muse, mutect2, varscan2
- HMGCLL1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 75/323 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.646); catalogued as rs772259012, COSV51441906; called by muse, mutect2, varscan2
- HOXB1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 392/959 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs879025404; called by muse, mutect2, varscan2
- HRG | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 261/657 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as rs886729944; called by muse, mutect2, varscan2
- HSD17B13 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 240/304 reads (79%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs747544810; called by muse, mutect2, varscan2
- HTR1A | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 168/470 reads (36%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs1273554893; called by muse, mutect2, varscan2
- HTR1A | c.646G>T p.G216W | Missense Mutation (SNP) | VAF 167/468 reads (36%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.824); catalogued as COSV60502398; called by muse, mutect2, varscan2
- HTR4 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); catalogued as rs1215993084, COSV58791571; called by muse, mutect2, varscan2
- IFIH1 | c.2548C>T p.R850* | Nonsense Mutation (SNP) | VAF 316/840 reads (38%) | catalogued as rs750804689, COSV55125658; ClinVar: uncertain significance; called by muse, mutect2
- IFNL2 | c.271-1G>A p.X91_splice | Splice Site (SNP) | VAF 301/718 reads (42%) | catalogued as rs772249678; called by muse, mutect2, varscan2
- IGF1R | c.2612C>T p.S871L | Missense Mutation (SNP) | VAF 95/672 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1198959559, COSV51277320; called by muse, mutect2, varscan2
- IGHG4 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 208/752 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779939638; called by muse, mutect2, varscan2
- IGHV1-46 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 206/505 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs531889359; called by muse, mutect2, varscan2
- IGHV2-70 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs568088145; called by muse, mutect2, varscan2
- IGHV3-16 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 142/420 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.783); catalogued as rs782709611; called by muse, mutect2, varscan2
- IGLV6-57 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 225/536 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.988); catalogued as rs1417851932; called by muse, mutect2, varscan2
- IGLV8-61 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 358/797 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs542479842, COSV66502625; called by muse, mutect2, varscan2
- IGSF21 | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 248/618 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.04); catalogued as rs767393509; called by muse, mutect2, varscan2
- IKBKE | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 301/776 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65626620; called by muse, mutect2, varscan2
- IL18RAP | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 241/669 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as rs142509174; called by muse, mutect2, varscan2
- IL1RL2 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 279/670 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV51816466; called by muse, mutect2, varscan2
- IL20RA | c.222C>T p.F74= | Splice Region (SNP) | VAF 95/266 reads (36%) | catalogued as COSV57361110; called by muse, mutect2, varscan2
- IL7R | c.1139C>T p.P380L | Missense Mutation (SNP) | VAF 237/928 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as COSV57409966; called by muse, mutect2, varscan2
- INPP5A | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 126/345 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61248333; called by muse, mutect2, varscan2
- INPP5B | c.2072C>T p.S691F (on ENST00000373023; = p.S611F on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 199/468 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV65962864; called by muse, mutect2, varscan2
- INSR | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 340/795 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV57169947; called by muse, mutect2, varscan2
- INTS6 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 520/772 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60879022; called by muse, mutect2, varscan2
- IP6K2 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 258/903 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1301547341; called by muse, mutect2, varscan2
- IQCA1L | c.2069G>A p.R690Q | Missense Mutation (SNP) | VAF 331/894 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs946252876, COSV51999331; called by muse, mutect2, varscan2
- IQCN | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 386/1003 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs146596461; called by muse, mutect2, varscan2
- IQCN | c.1147C>T p.P383S | Missense Mutation (SNP) | VAF 388/1012 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV66573577; called by muse, mutect2, varscan2
- IQSEC3 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 211/1558 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); catalogued as rs781892955; called by muse, mutect2, varscan2
- IRAK2 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 195/714 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56528581; called by muse, mutect2, varscan2
- IRGC | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 493/1176 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.289); catalogued as rs778870905; called by muse, mutect2
- ISLR | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 361/1011 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs868123537, COSV99997227; called by muse, mutect2, varscan2
- ITGA1 | c.2981C>T p.S994F | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV50901044; called by muse, mutect2, varscan2
- ITGA11 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 557/1065 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs544682550; called by muse, mutect2, varscan2
- ITGA11 | c.1690G>A p.A564T | Missense Mutation (SNP) | VAF 177/1025 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1325429944; called by muse, mutect2, varscan2
- ITIH5 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 294/526 reads (56%) | SIFT tolerated (0.81); PolyPhen benign (0.031); catalogued as rs369347222; called by muse, mutect2, varscan2
- ITLN1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 417/1040 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as rs372878387; called by muse, mutect2, varscan2
- IVL | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 419/1135 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1220421012; called by muse, mutect2, varscan2
- JMY | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 127/388 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs772805107, COSV68662815; called by muse, mutect2, varscan2
- KANSL1L | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 172/402 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762505094, COSV55993885; called by muse, mutect2, varscan2
- KAT6B | c.425C>T p.T142I | Missense Mutation (SNP) | VAF 188/551 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1054836015; called by muse, mutect2, varscan2
- KBTBD12 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 141/193 reads (73%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.001); catalogued as COSV100675495; called by muse, mutect2, varscan2
- KBTBD12 | c.1098G>A p.W366* | Nonsense Mutation (SNP) | VAF 214/312 reads (69%) | catalogued as COSV59681272; called by muse, mutect2, varscan2
- KCNA6 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 394/730 reads (54%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs866418364, COSV54974491; called by muse, mutect2, varscan2
- KCND3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 277/748 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.062); catalogued as rs764928165, COSV56188774; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ5 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 367/511 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148462487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 185/697 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV57973296; called by muse, mutect2, varscan2
- KCNK5 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 215/910 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.022); catalogued as COSV100851864; called by muse, mutect2, varscan2
- KCNU1 | c.2498C>T p.S833F | Missense Mutation (SNP) | VAF 228/619 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101299116; called by muse, mutect2, varscan2
- KCTD16 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 187/435 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769455523; called by muse, mutect2, varscan2
- KHDRBS2 | c.869del p.N290Tfs*20 | Frame Shift Del (DEL) | VAF 124/376 reads (33%) | catalogued as COSV99838937; called by mutect2, pindel, varscan2
- KIAA0319 | c.3022G>A p.E1008K | Missense Mutation (SNP) | VAF 127/625 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs866430826; called by muse, mutect2
- KIAA1210 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 174/216 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV68177424; called by muse, mutect2, varscan2
- KIAA1614 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 221/852 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs200156750, COSV100851235, COSV62550572; called by muse, mutect2, varscan2
- KIF18B | c.2042C>T p.S681F (on ENST00000593135 / NM_001265577.2; = p.S693F on NM_001264573.2) | Missense Mutation (SNP) | VAF 449/1045 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs371854103; called by muse, mutect2, varscan2
- KIF18B | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 300/671 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV59275034; called by muse, mutect2, varscan2
- KIF26B | c.4700C>T p.A1567V | Missense Mutation (SNP) | VAF 534/1329 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs763980355; called by muse, mutect2, varscan2
- KIF2B | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 375/912 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.59); catalogued as rs1229299890, COSV52127464; called by muse, mutect2, varscan2
- KIF5A | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 261/332 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV54056649; called by muse, mutect2, varscan2
- KIF6 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 166/452 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.421); catalogued as COSV54674181, COSV54684039; called by muse, mutect2, varscan2
- KL | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 216/1305 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs1386106688; called by muse, mutect2, varscan2
- KL | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 182/990 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779841444, COSV104430440; called by muse, mutect2, varscan2
- KLHL14 | c.1056G>A p.W352* | Nonsense Mutation (SNP) | VAF 273/388 reads (70%) | catalogued as COSV63834569; called by muse, mutect2, varscan2
- KMT2C | c.5396C>T p.S1799L | Missense Mutation (SNP) | VAF 285/718 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as COSV51425929; called by muse, mutect2, varscan2
- KNTC1 | c.4495C>T p.L1499F | Missense Mutation (SNP) | VAF 357/472 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs772694843, COSV61083809; called by muse, mutect2, varscan2
- KRT10 | c.1408G>A p.G470S | Missense Mutation (SNP) | VAF 404/968 reads (42%) | SIFT tolerated (0.99); PolyPhen benign (0.339); catalogued as rs1334942148; called by muse, mutect2, varscan2
- KRT15 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 172/452 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as rs1423698306, COSV54180898; called by muse, mutect2, varscan2
- KRT23 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 255/627 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.145); catalogued as rs897151182, COSV52926966, COSV52927053; called by muse, mutect2, varscan2
- KRT24 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 202/506 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs749502511; called by muse, mutect2, varscan2
- KRT24 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 361/741 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1309519674; called by muse, mutect2, varscan2
- KRT25 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 420/1065 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs754517768, COSV100380021, COSV56444403; called by muse, mutect2, varscan2
- KRT28 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 390/942 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as COSV100137789; called by muse, mutect2, varscan2
- KRT33B | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 395/891 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs759598244; called by muse, mutect2, varscan2
- KRTAP10-11 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 244/665 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs199741257; called by muse, mutect2, varscan2
- KRTAP4-6 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 629/1843 reads (34%) | SIFT deleterious (0); catalogued as COSV100624081; called by muse, mutect2, varscan2
- L3MBTL1 | c.1601G>A p.R534Q (on ENST00000418998 / NM_001377303.1; = p.R444Q on NM_015478.7) | Missense Mutation (SNP) | VAF 193/333 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs756904545, COSV64228025; called by muse, mutect2, varscan2
- LAMA5 | c.5137C>T p.R1713C | Missense Mutation (SNP) | VAF 168/681 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs374046052; called by muse, mutect2, varscan2
- LAMB1 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 397/995 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs777314468, COSV55963235; called by muse, mutect2, varscan2
- LAMB3 | c.2101G>A p.E701K | Missense Mutation (SNP) | VAF 326/749 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV61915717; called by muse, mutect2, varscan2
- LAMB4 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 473/1055 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs770761096; called by muse, mutect2, varscan2
- LAMC2 | c.2747G>A p.G916E | Missense Mutation (SNP) | VAF 191/372 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777067409, COSV51454380; called by muse, mutect2
- LAMC3 | c.4256G>A p.R1419Q | Missense Mutation (SNP) | VAF 148/391 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs201597071, COSV62653934; called by muse, mutect2, varscan2
- LBP | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 256/504 reads (51%) | SIFT tolerated (0.79); PolyPhen benign (0.194); catalogued as rs757338505; called by muse, mutect2, varscan2
- LCA5L | c.45C>A p.F15L | Missense Mutation (SNP) | VAF 116/319 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs555546608, COSV55744077; called by muse, mutect2, varscan2
- LCE1F | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 449/1132 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as rs1329567979, COSV57668676; called by muse, mutect2, varscan2
- LCK | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 420/767 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs759646706, COSV60739481; called by muse, mutect2, varscan2
- LCNL1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 231/560 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375042346; called by muse, mutect2, varscan2
- LDLR | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 379/911 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.073); catalogued as rs1368762538; called by muse, mutect2, varscan2
- LEXM | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 293/767 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200886761, COSV64024196; called by muse, mutect2, varscan2
- LILRA2 | c.1360G>A p.G454S (on ENST00000391738 / NM_001130917.3; = p.G437S on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 539/1186 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV99253784; called by muse, mutect2, varscan2
- LILRB5 | c.1202C>T p.S401F | Missense Mutation (SNP) | VAF 239/506 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); catalogued as COSV60254414; called by muse, mutect2, varscan2
- LIMCH1 | c.1073G>A p.R358K | Missense Mutation (SNP) | VAF 229/310 reads (74%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58287195; called by muse, mutect2, varscan2
- LPCAT4 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 164/580 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs564033666; called by muse, mutect2, varscan2
- LPIN1 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 268/705 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs185471985, COSV56763136; called by muse, mutect2, varscan2
- LRFN5 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 186/490 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53279447; called by muse, mutect2, varscan2
- LRP12 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 322/603 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV52628890; called by muse, mutect2, varscan2
- LRP1B | c.12596G>A p.G4199E | Missense Mutation (SNP) | VAF 277/680 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs868543953, COSV67186838; called by muse, mutect2, varscan2
- LRP1B | c.9967C>T p.R3323C | Missense Mutation (SNP) | VAF 169/414 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1328117748, COSV67187455; called by muse, mutect2, varscan2
- LRP1B | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 309/781 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67213531; called by muse, mutect2, varscan2
- LRP1B | c.1405A>G p.T469A | Missense Mutation (SNP) | VAF 133/345 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV67226319; called by muse, mutect2, varscan2
- LRP2 | c.11206C>T p.R3736C | Missense Mutation (SNP) | VAF 288/637 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275575465, COSV55544664; called by muse, mutect2, varscan2
- LRP4 | c.2261G>A p.R754Q | Missense Mutation (SNP) | VAF 147/575 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs768053076, COSV66135741; called by muse, mutect2, varscan2
- LRRC2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 112/467 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs758828256, COSV56126105, COSV99947331; called by muse, mutect2, varscan2
- LRRC34 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 144/380 reads (38%) | catalogued as rs1170217067; called by muse, mutect2, varscan2
- LRRC4C | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 291/608 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs773078198, COSV53433740; called by muse, mutect2, varscan2
- LRRC70 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 178/496 reads (36%) | catalogued as rs752188484; called by muse, mutect2, varscan2
- LRRN1 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 197/698 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267599792, COSV60013540; called by muse, mutect2, varscan2
- LRRTM1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 414/1018 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as rs570950310, COSV54446546; called by muse, mutect2, varscan2
- LRRTM4 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 364/843 reads (43%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.06); catalogued as COSV69153795; called by muse, varscan2
- LSMEM2 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 231/433 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV57113124; called by muse, mutect2, varscan2
- MAG | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 470/1070 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV100728047; called by muse, mutect2, varscan2
- MAGEA1 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 217/269 reads (81%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63118372; called by muse, mutect2, varscan2
- MAGEB5 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 446/531 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV66869265; called by muse, mutect2, varscan2
- MAGEC1 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 234/314 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99596422; called by muse, mutect2, varscan2
- MAGEL2 | c.2467G>A p.D823N | Missense Mutation (SNP) | VAF 156/598 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as COSV100045767; called by muse, mutect2, varscan2
- MAN2A1 | c.2941C>T p.R981* | Nonsense Mutation (SNP) | VAF 99/294 reads (34%) | catalogued as rs761015143, COSV54846814; called by muse, mutect2, varscan2
- MAN2B1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 375/910 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1289169338, COSV54419097; called by muse, mutect2, varscan2
- MAP3K6 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 394/755 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs146598623; called by muse, mutect2, varscan2
- MAP7D1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 140/525 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs759769970; called by mutect2, varscan2
- MAPK11 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 270/671 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53135526; called by muse, mutect2, varscan2
- MARCHF10 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 245/699 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs1375164901; called by muse, mutect2, varscan2
- MARCO | c.1090G>C p.G364R | Missense Mutation (SNP) | VAF 222/560 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59057052; called by muse, mutect2, varscan2
- MBD5 | c.3251C>T p.S1084F | Missense Mutation (SNP) | VAF 312/722 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV101290277; called by muse, mutect2, varscan2
- MCF2L2 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 232/614 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61061298; called by muse, varscan2
- MCM3 | c.209C>T p.S70F (on ENST00000229854 / NM_001366374.2; = p.F22= on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.471); catalogued as rs1487344814; called by muse, varscan2
- MCPH1 | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 289/792 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769776443, COSV60911222; called by muse, mutect2, varscan2
- MCUB | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 375/514 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54460263; called by muse, mutect2, varscan2
- MDM1 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 213/288 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.261); catalogued as COSV57448632; called by muse, mutect2, varscan2
- MECOM | c.922C>T p.P308S (on ENST00000468789 / NM_001105078.4; = p.P496S on NM_004991.4) | Missense Mutation (SNP) | VAF 334/762 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52959050; called by muse, mutect2, varscan2
- MED25 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 196/472 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs1001322913, COSV57207305; called by muse, mutect2, varscan2
- MEF2D | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 418/1141 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1305911253; called by muse, mutect2, varscan2
- MEI1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 227/580 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55903106; called by muse, mutect2, varscan2
- METTL11B | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 337/609 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV63029953, COSV63030280; called by muse, mutect2, varscan2
- MGAM | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 270/681 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs779098977, COSV71884967; called by muse, mutect2, varscan2
- MGAM | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 280/1447 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs866544940, COSV72074972; called by muse, mutect2, varscan2
- MIA3 | c.1727C>T p.S576F | Missense Mutation (SNP) | VAF 451/809 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV60513444; called by muse, mutect2, varscan2
- MITD1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 282/606 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202212055; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 155/208 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56617077; called by muse, mutect2, varscan2
- MROH2A | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 216/520 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs967875828; called by muse, mutect2, varscan2
- MROH5 | c.2209G>A p.D737N | Missense Mutation (SNP) | VAF 322/485 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs371347936; called by muse, mutect2, varscan2
- MROH7 | c.3638C>T p.S1213F | Missense Mutation (SNP) | VAF 303/737 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs1373000656, COSV64887248; called by muse, mutect2, varscan2
- MROH9 | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 110/470 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752447106; called by muse, mutect2, varscan2
- MRPL19 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 166/426 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs947209529, COSV62566478; called by muse, mutect2, varscan2
- MTBP | c.2305C>T p.H769Y | Missense Mutation (SNP) | VAF 197/388 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.125); catalogued as rs1177215121, COSV59960765; called by muse, varscan2
- MTNR1A | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 373/498 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs1245979910; called by muse, mutect2, varscan2
- MTNR1B | c.757A>G p.M253V | Missense Mutation (SNP) | VAF 395/980 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs1373695611; called by muse, mutect2, varscan2
- MTNR1B | c.758T>C p.M253T | Missense Mutation (SNP) | VAF 396/974 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.366); catalogued as rs748867223, COSV99925121; called by muse, mutect2, varscan2
- MTOR | c.5431C>T p.R1811C | Missense Mutation (SNP) | VAF 370/936 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1258909652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTUS2 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 677/954 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV70922428; called by muse, mutect2, varscan2
- MUC12 | c.13123C>T p.P4375S (on ENST00000379442; = p.P4232S on NM_001164462.1) | Missense Mutation (SNP) | VAF 448/2179 reads (21%) | SIFT deleterious (0.05); catalogued as rs778933247; called by muse, mutect2, varscan2
- MUC16 | c.41599G>A p.D13867N | Missense Mutation (SNP) | VAF 306/746 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.968); catalogued as rs1296301073; called by muse, mutect2, varscan2
- MUC16 | c.38048G>A p.G12683E | Missense Mutation (SNP) | VAF 159/424 reads (38%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs751445901; called by muse, mutect2, varscan2
- MUC16 | c.37810G>A p.E12604K | Missense Mutation (SNP) | VAF 134/468 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749277251, COSV101197836, COSV67466588; called by muse, mutect2, varscan2
- MUC16 | c.31199G>A p.R10400K | Missense Mutation (SNP) | VAF 237/654 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.1); catalogued as COSV67464408; called by muse, mutect2, varscan2
- MUC16 | c.28573A>T p.T9525S | Missense Mutation (SNP) | VAF 389/906 reads (43%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.556); catalogued as rs1270105082; called by muse, mutect2, varscan2
- MUC16 | c.23413G>A p.D7805N | Missense Mutation (SNP) | VAF 347/807 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.184); catalogued as rs761251311, COSV67488271; called by muse, mutect2, varscan2
- MUC16 | c.15701C>T p.S5234F | Missense Mutation (SNP) | VAF 326/748 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV67445111; called by muse, mutect2, varscan2
- MUC16 | c.7991C>T p.S2664F | Missense Mutation (SNP) | VAF 285/713 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67477336; called by muse, mutect2, varscan2
- MUC16 | c.7114G>A p.D2372N | Missense Mutation (SNP) | VAF 202/452 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs867466995, COSV67460769; called by muse, mutect2, varscan2
- MUC17 | c.2711C>T p.S904L | Missense Mutation (SNP) | VAF 399/1197 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs139093882, COSV60299425; called by muse, mutect2, varscan2
- MUC17 | c.6653G>A p.G2218E | Missense Mutation (SNP) | VAF 402/952 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1474855225; called by muse, varscan2
- MUC3A | c.7532C>T p.S2511F | Missense Mutation (SNP) | VAF 370/930 reads (40%) | SIFT tolerated, low confidence (0.08); catalogued as rs541628829, COSV100114521, COSV100115421; called by muse, mutect2, varscan2
- MUC4 | c.13728G>A p.W4576* (on ENST00000463781 / NM_018406.7; = p.W340* on NM_004532.6) | Nonsense Mutation (SNP) | VAF 553/1338 reads (41%) | catalogued as COSV57773311; called by muse, mutect2, varscan2
- MX1 | c.1813C>T p.L605F | Missense Mutation (SNP) | VAF 182/529 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1569001852; called by muse, mutect2, varscan2
- MYF5 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 125/501 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1381547702; called by muse, mutect2, varscan2
- MYF6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 171/310 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs781756867, COSV99952722; called by muse, varscan2
- MYH1 | c.3863C>T p.S1288L | Missense Mutation (SNP) | VAF 213/277 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV99875976; called by muse, mutect2, varscan2
- MYH13 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs756858193; called by muse, mutect2, varscan2
- MYH15 | c.3432G>A p.M1144I | Missense Mutation (SNP) | VAF 151/555 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs747627053; called by muse, mutect2, varscan2
- MYH4 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 282/388 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs558519475; called by muse, mutect2, varscan2
- MYH6 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV62449803; called by muse, mutect2
- MYH9 | c.5675C>T p.S1892F | Missense Mutation (SNP) | VAF 485/1138 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.079); catalogued as rs1450702017; called by muse, mutect2, varscan2
- MYLK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 279/695 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs564792567, COSV60604501; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 455/574 reads (79%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs981927941, COSV52756314; called by muse, mutect2, varscan2
- MYO16 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 115/660 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs776925771, COSV51803396; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 361/808 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2, varscan2
- MYO18B | c.5881G>A p.D1961N | Missense Mutation (SNP) | VAF 275/713 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.385); catalogued as COSV59144909; called by muse, varscan2
- MYO18B | c.6323G>A p.R2108Q | Missense Mutation (SNP) | VAF 279/615 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs761193684, COSV59142649; called by muse, mutect2, varscan2
- MYO5C | c.898C>T p.R300* | Nonsense Mutation (SNP) | VAF 359/902 reads (40%) | catalogued as rs1241157229, COSV55909254; called by muse, mutect2, varscan2
- MYO6 | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 88/274 reads (32%) | catalogued as rs369889326; called by muse, mutect2, varscan2
- MYO7B | c.5780C>T p.S1927L | Missense Mutation (SNP) | VAF 348/852 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs754903067, COSV61441918; called by muse, mutect2, varscan2
- MYOCD | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 369/530 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58514224; called by muse, varscan2
- MYOM2 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 315/763 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs148337899; called by muse, mutect2, varscan2
- NAALAD2 | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 219/548 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV58960082; called by muse, mutect2, varscan2
- NAT10 | c.1408C>T p.R470* | Nonsense Mutation (SNP) | VAF 148/587 reads (25%) | catalogued as rs765183435; called by muse, mutect2, varscan2
- NAV2 | c.2488C>T p.R830* (on ENST00000396087 / NM_001244963.2; = p.R807* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 190/788 reads (24%) | catalogued as rs865835391, COSV62319361; called by muse, mutect2, varscan2
- NBEAL1 | c.5857C>A p.L1953I | Missense Mutation (SNP) | VAF 220/616 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV68916340; called by muse, mutect2, varscan2
- NBR1 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 163/433 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57835542; called by muse, mutect2, varscan2
- NCKAP5 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 345/859 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs755256419; called by muse, mutect2, varscan2
- NCOA1 | c.3727G>A p.A1243T | Missense Mutation (SNP) | VAF 241/622 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs1435683283, COSV99946009; called by muse, mutect2, varscan2
- NCOA2 | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 144/579 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV71763953; called by muse, mutect2, varscan2
- NCR1 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 441/1103 reads (40%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52557836; called by muse, mutect2, varscan2
- NCR1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 551/1405 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.53); catalogued as COSV52556814; called by muse, mutect2, varscan2
- NCR1 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 551/1411 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs774857066, COSV52557516; called by muse, mutect2, varscan2
- NDST3 | c.2222G>A p.R741K | Missense Mutation (SNP) | VAF 332/425 reads (78%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs1293181568; called by muse, mutect2, varscan2
- NEB | c.13879G>A p.D4627N | Missense Mutation (SNP) | VAF 235/569 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs377429434; called by muse, mutect2, varscan2
- NEB | c.5615C>T p.P1872L | Missense Mutation (SNP) | VAF 362/785 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs760925535, COSV51121097; called by muse, mutect2, varscan2
- NEB | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 254/644 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs377599060; called by muse, mutect2, varscan2
- NEBL | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 145/572 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746529858, COSV101009015, COSV65802861; called by muse, mutect2, varscan2
- NEBL | c.1382G>A p.G461E | Missense Mutation (SNP) | VAF 153/539 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); catalogued as rs768161805, COSV65802571; called by muse, mutect2, varscan2
- NEFH | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 396/949 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV100151669; called by muse, mutect2, varscan2
- NES | c.3920C>T p.S1307F | Missense Mutation (SNP) | VAF 493/1145 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63960804; called by muse, mutect2, varscan2
- NEUROD1 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 348/813 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1349732855; called by muse, mutect2, varscan2
- NEXMIF | c.2695G>A p.E899K | Missense Mutation (SNP) | VAF 473/555 reads (85%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV50041754, COSV50045392; called by muse, mutect2, varscan2
- NHSL2 | c.1622G>T p.R541M (on ENST00000510661; = p.R907M on NM_001013627.2) | Missense Mutation (SNP) | VAF 208/247 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.326); catalogued as COSV101029995; called by muse, mutect2, varscan2
- NIBAN3 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 315/735 reads (43%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as rs1210760308; called by muse, mutect2, varscan2
- NID2 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 141/395 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1468289403, COSV53495868; called by muse, mutect2, varscan2
- NID2 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 154/460 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as COSV53503403; called by muse, varscan2
- NID2 | c.2150C>T p.S717F | Missense Mutation (SNP) | VAF 190/464 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV53497417, COSV99356589; called by muse, varscan2
- NIPSNAP2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 305/728 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59050621; called by muse, mutect2, varscan2
- NLN | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768326002; called by muse, mutect2, varscan2
- NLRP3 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 290/750 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs767011471, COSV60220242, COSV60225995; called by muse, mutect2, varscan2
- NLRP4 | c.1414C>T p.H472Y | Missense Mutation (SNP) | VAF 366/976 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56713597; called by muse, mutect2
- NLRP4 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 179/450 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.948); catalogued as COSV56724524; called by muse, mutect2, varscan2
- NLRP8 | c.1238G>A p.G413E | Missense Mutation (SNP) | VAF 299/688 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs866751626, COSV99405586; called by muse, mutect2, varscan2
- NLRP9 | c.524G>A p.W175* | Nonsense Mutation (SNP) | VAF 364/851 reads (43%) | catalogued as rs1466339921, COSV100242410, COSV100243693; called by muse, mutect2, varscan2
- NME1-NME2 | c.604C>T p.P202S (on ENST00000555572; = p.P177S on NM_001018136.3) | Missense Mutation (SNP) | VAF 260/682 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.144); catalogued as rs1297017824; called by muse, mutect2, varscan2
- NME8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 207/449 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs369542497; called by muse, mutect2, varscan2
- NOTCH3 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 428/1023 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475080033, CM003015; called by muse, mutect2, varscan2
- NOX5 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 393/990 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs776336697; called by muse, mutect2, varscan2
- NOX5 | c.1914G>A p.W638* | Nonsense Mutation (SNP) | VAF 103/563 reads (18%) | catalogued as rs1390603839; called by muse, mutect2, varscan2
- NPAP1 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 336/703 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs865895928, COSV61506356; called by muse, mutect2, varscan2
- NPHP4 | c.3754C>A p.L1252I | Missense Mutation (SNP) | VAF 381/935 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs398124290, COSV65392904; called by muse, mutect2, varscan2
- NPHS1 | c.3551C>T p.P1184L | Missense Mutation (SNP) | VAF 258/594 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs1010795962; called by muse, mutect2, varscan2
- NPR1 | c.2233G>A p.D745N | Missense Mutation (SNP) | VAF 209/519 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.042); catalogued as COSV64117958; called by muse, mutect2, varscan2
- NPR2 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 182/562 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs778410447, COSV100709796; called by muse, mutect2, varscan2
- NRXN2 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 229/803 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV55459527; called by muse, mutect2, varscan2
- NSUN6 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 264/499 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs867410434, COSV66031726; called by muse, mutect2, varscan2
- NT5DC4 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 398/951 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs551167032; called by muse, mutect2, varscan2
- NUAK1 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 201/789 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs186215853; called by muse, mutect2, varscan2
- NUAK1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 329/595 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs772183684, COSV54605730; called by muse, mutect2, varscan2
- NUSAP1 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 248/533 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as rs775051382, COSV52971848; called by muse, mutect2, varscan2
- NYAP2 | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 205/461 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV56015512; called by muse, mutect2, varscan2
- NYNRIN | c.3390G>A p.W1130* | Nonsense Mutation (SNP) | VAF 214/560 reads (38%) | catalogued as COSV66841090; called by muse, mutect2, varscan2
- OCM2 | c.63C>T p.D21= | Splice Region (SNP) | VAF 225/572 reads (39%) | catalogued as rs1354864552; called by muse, mutect2, varscan2
- OR10A5 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 171/597 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs867881604; called by muse, mutect2, varscan2
- OR10H2 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 228/596 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1055546295, COSV100008615; called by muse, mutect2, varscan2
- OR10H4 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 308/743 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs868676405; called by muse, mutect2, varscan2
- OR10J1 | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373330432, COSV101419901, COSV71128120; called by muse, mutect2, varscan2
- OR10J3 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 206/780 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.792); catalogued as rs867791135, COSV59953822; called by muse, varscan2
- OR10J3 | c.359G>A p.G120E | Missense Mutation (SNP) | VAF 372/666 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59954348; called by muse, varscan2
- OR10Z1 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 147/656 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1557913278; called by muse, mutect2, varscan2
- OR11H6 | c.916C>T p.L306F | Missense Mutation (SNP) | VAF 123/383 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as rs866042152, COSV59645560; called by muse, mutect2, varscan2
- OR13C8 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 208/738 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV58610625; called by muse, mutect2, varscan2
- OR13C8 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 282/517 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58612259; called by muse, mutect2, varscan2
- OR13G1 | c.721C>T p.H241Y | Missense Mutation (SNP) | VAF 275/732 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62943959; called by muse, mutect2, varscan2
- OR13H1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 169/226 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100088332; called by muse, mutect2, varscan2
- OR2A2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 294/709 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV68872002; called by muse, mutect2, varscan2
- OR2F1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 262/634 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101231319, COSV67330780, COSV67332271; called by muse, mutect2, varscan2
- OR2G6 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 338/803 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58574474; called by muse, mutect2, varscan2
- OR2M5 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 377/916 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV63546261; called by muse, mutect2, varscan2
- OR2V1 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs748791857; called by muse, mutect2, varscan2
- OR4K5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 142/341 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV60002682; called by muse, mutect2, varscan2
- OR4N5 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 171/495 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1329156063; called by muse, mutect2, varscan2
- OR4Q2 | c.525+1G>A | Missense Mutation (SNP) | VAF 176/447 reads (39%) | catalogued as rs895174410; called by muse, mutect2
- OR51B5 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 165/563 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1435926857, COSV56175601; called by muse, mutect2, varscan2
- OR51G1 | c.957G>A p.W319* | Nonsense Mutation (SNP) | VAF 74/282 reads (26%) | catalogued as rs769264009; called by muse, mutect2, varscan2
- OR51I1 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 154/640 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100970755, COSV100971807; called by muse, mutect2, varscan2
- OR51L1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 153/564 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as rs1212251668, COSV58624046; called by muse, mutect2, varscan2
- OR52E8 | c.296C>T p.S99F | Missense Mutation (SNP) | VAF 369/707 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV66204679; called by muse, mutect2, varscan2
- OR52L1 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 246/465 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs756450029; called by muse, mutect2, varscan2
- OR52N1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 292/595 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100398643; called by muse, mutect2, varscan2
- OR52W1 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 185/688 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.168); catalogued as rs780486061; called by muse, mutect2, varscan2
- OR56A3 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 359/694 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as COSV61569057; called by muse, mutect2, varscan2
- OR56B1 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 152/528 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100402664; called by muse, mutect2, varscan2
- OR5A1 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 140/700 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV57377354; called by muse, mutect2, varscan2
- OR5AC2 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 366/672 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV62279154; called by muse, mutect2, varscan2
- OR5K1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 190/362 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV100221052, COSV60304383; called by muse, mutect2, varscan2
- OR5L1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 306/448 reads (68%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs149863919, COSV61733695; called by muse, mutect2, varscan2
- OR6Y1 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 144/625 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV56928014, COSV56930171; called by muse, mutect2, varscan2
- OR8B4 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 319/405 reads (79%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.52); catalogued as rs752372117, COSV62070702; called by muse, mutect2, varscan2
- OR8K5 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 159/214 reads (74%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376114385, COSV100537278; called by muse, mutect2, varscan2
- OSBPL5 | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 160/639 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55141042; called by muse, mutect2, varscan2
- OTOGL | c.5797G>A p.E1933K (on ENST00000547103; = p.E1924K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 205/381 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs756958173, COSV54017465; called by muse, mutect2, varscan2
- PAK2 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 176/488 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59080200; called by muse, mutect2
- PAK4 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 529/1331 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as rs770215974; called by muse, mutect2, varscan2
- PAK5 | c.2060A>G p.Q687R | Missense Mutation (SNP) | VAF 171/594 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100781661; called by muse, mutect2, varscan2
- PAK5 | c.1441G>A p.D481N | Missense Mutation (SNP) | VAF 303/583 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV62037795; called by muse, mutect2, varscan2
- PAK5 | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 149/593 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62031841; called by muse, mutect2, varscan2
- PAPPA2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 418/714 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV62774642; called by muse, mutect2, varscan2
- PAPPA2 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 167/699 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs775169340, COSV62776814, COSV62779600; called by muse, mutect2, varscan2
- PARP6 | c.1861C>G p.R621G | Missense Mutation (SNP) | VAF 111/709 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53002555; called by muse, mutect2, varscan2
- PARP9 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 302/694 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs1478334042; called by muse, mutect2, varscan2
- PAX6 | c.1088C>T p.S363L | Missense Mutation (SNP) | VAF 172/637 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1411880763; called by muse, mutect2, varscan2
- PAX8 | c.779G>A p.G260D | Missense Mutation (SNP) | VAF 283/669 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1164452252, COSV99640108; called by muse, mutect2, varscan2
- PCARE | c.3140G>A p.R1047Q | Missense Mutation (SNP) | VAF 323/764 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs759269733, COSV100527676, COSV59053819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH15 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 147/377 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as CM142134, COSV57306770; called by muse, mutect2, varscan2
- PCDH15 | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 109/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1488054571, COSV57348197; called by muse, mutect2, varscan2
- PCDHA1 | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 235/702 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65374439; called by muse, mutect2, varscan2
- PCDHA4 | c.1600C>T p.Q534* | Nonsense Mutation (SNP) | VAF 223/749 reads (30%) | catalogued as COSV100793088; called by muse, mutect2, varscan2
- PCDHA8 | c.2039C>T p.S680L | Missense Mutation (SNP) | VAF 177/559 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs782556523; called by muse, mutect2, varscan2
- PCDHA9 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 207/518 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as COSV65323835; called by muse, mutect2, varscan2
- PCDHB12 | c.2111C>T p.S704L | Missense Mutation (SNP) | VAF 266/818 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV53395531; called by muse, mutect2, varscan2
- PCDHB3 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 165/499 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.108); catalogued as COSV50585999; called by muse, mutect2, varscan2
- PCDHB8 | c.2174G>A p.R725H | Missense Mutation (SNP) | VAF 218/597 reads (37%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.582); catalogued as COSV50754695; called by muse, mutect2, varscan2
- PCDHGA12 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 286/759 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52760881; called by muse, mutect2, varscan2
- PCLO | c.15236C>T p.S5079L | Missense Mutation (SNP) | VAF 279/756 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs750960950, COSV61623630, COSV61653389; called by muse, mutect2, varscan2
- PCLO | c.11044C>T p.P3682S | Missense Mutation (SNP) | VAF 263/637 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201832967; called by muse, mutect2, varscan2
- PCLO | c.10930G>A p.E3644K | Missense Mutation (SNP) | VAF 221/563 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61615258; called by muse, mutect2, varscan2
- PCLO | c.8896C>T p.R2966C | Missense Mutation (SNP) | VAF 359/872 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1173009964, COSV61649863; called by muse, mutect2, varscan2
- PCLO | c.6328G>T p.V2110F | Missense Mutation (SNP) | VAF 322/737 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV61617039; called by mutect2, varscan2
- PCLO | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 351/850 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.187); catalogued as COSV61617770; called by muse, mutect2, varscan2
- PCNX2 | c.3853C>T p.H1285Y | Missense Mutation (SNP) | VAF 137/572 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV50815782; called by muse, mutect2, varscan2
- PDE11A | c.1964G>A p.R655K | Missense Mutation (SNP) | VAF 224/547 reads (41%) | SIFT tolerated (0.76); PolyPhen benign (0.018); catalogued as COSV99613803; called by muse, mutect2, varscan2
- PDE1A | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 186/508 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs762592414, COSV59537784; called by muse, mutect2, varscan2
- PDE4DIP | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 385/815 reads (47%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as rs1553604534; called by muse, mutect2, varscan2
- PDE6B | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 239/317 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs146116505; called by muse, mutect2, varscan2
- PDE9A | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs769496314, COSV52327025; called by muse, mutect2, varscan2
- PDGFRA | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 198/279 reads (71%) | SIFT tolerated (0.7); PolyPhen benign (0.164); catalogued as COSV57268314; called by muse, mutect2, varscan2
- PDGFRB | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 192/465 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV55804321; called by muse, mutect2, varscan2
- PDZD7 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 230/683 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs1462342137; called by muse, mutect2, varscan2
- PDZRN4 | c.2933G>A p.G978D (on ENST00000402685 / NM_001164595.2; = p.G720D on NM_013377.4) | Missense Mutation (SNP) | VAF 281/661 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.218); catalogued as COSV54195041; called by muse, mutect2, varscan2
- PEAR1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 109/482 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52775863; called by muse, mutect2, varscan2
2,779 further variants in this file (1,471 protein-altering or splice-affecting, 1,184 silent, 124 other) are not listed here.
